Gene-level copy-number profile of tumor specimen HCM-CSHL-0073-C25-01B from HCMI case HCM-CSHL-0073-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 55.3 years (20,210 days).
Specimen HCM-CSHL-0073-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f536524e-891a-4780-8da7-f633a79269f4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0073-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/c55e4871-7e71-4d0a-b3ef-942624a85bf0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 3; copy number 2: 10,925; copy number 3: 533; copy number 4: 43,803; copy number 5: 1,630; copy number 6: 1,898; copy number 8: 45; copy number 12: 9.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,523,857, 3 genes: ANKRD20A17P, AC119751.5, AC119751.2.
- chr4:49,561,285–49,589,529, 4 genes: AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:21,329,665–23,438,700, 39 genes: KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:98,115,885–99,070,792, 13 genes (within-gene range 0–2): Metazoa_SRP, CORO2A, TBC1D2, MIR6854, AL360081.1, GABBR2, SEPTIN7P7, ANKS6, GALNT12, AL136084.1, NME2P3, COL15A1, AL136084.2.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–2): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:16,029,157–16,351,797, 9 genes, copy number 12 (within-gene range 4–12): NCOR1, AC002553.1, RPLP1P11, RPL22P21, RNU6-314P, RNU6-862P, RN7SL442P, PIGL, MIR1288.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
